Somatic mutation profile of tumor specimen d068de5f-8394-46bc-b03a-c6dc9c (aliquot d068de5f-8394-46bc-b03a-c6dc9c_D6_2) from CPTAC case 09CO015, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen d068de5f-8394-46bc-b03a-c6dc9c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28bee51f-3b77-42b4-992a-8bfbb398e74a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 2056d495-4d6d-4d84-a29a-80373d (Blood Derived Normal), aliquot 2056d495-4d6d-4d84-a29a-80373d_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e299884-31bf-43d8-8734-e076ef8d63f4

The open-access MAF lists 132 somatic variants for this specimen: 86 protein-altering or splice-affecting, 27 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 27, Intron 10, Nonsense Mutation 4, RNA 4, 5'UTR 3, Splice Site 3, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 195/381 reads (51%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs184802755, COSV59373041; called by muse, mutect2, varscan2
- ADGRA2 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781535229, COSV99605071; called by muse, mutect2, varscan2
- ALPG | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377699892; called by muse, mutect2, varscan2
- ALPL | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757771793, CM068249; called by muse, mutect2, varscan2
- CFAP57 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV65264289; called by muse, mutect2, varscan2
- CHST15 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.421); catalogued as rs200319997, COSV60559964; called by muse, mutect2, varscan2
- DHX9 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62360664; called by muse, mutect2
- DNAH5 | c.6332G>A p.R2111H | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs946204829, COSV54202034; called by muse, mutect2, varscan2
- DPP10 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.43); catalogued as rs1416501116; called by muse, mutect2
- EML5 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.531); catalogued as rs369731084; called by muse, mutect2, varscan2
- FAM83H | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV66354169; called by muse, mutect2, varscan2
- FUT9 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56145617; called by muse, mutect2, varscan2
- GALNT17 | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 92/131 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs1315959460; called by muse, mutect2, varscan2
- GLIS3 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1436820151; called by muse, mutect2, varscan2
- GPR26 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs755508152, COSV99500873; called by muse, mutect2, varscan2
- HTR1B | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 106/392 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64051581; called by muse, varscan2
- KCNA10 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 170/488 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768535829, COSV63904462; called by muse, mutect2, varscan2
- KCNB1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100870472; called by muse, mutect2, varscan2
- KCNH4 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs201093626, COSV52921288; called by muse, mutect2, varscan2
- KRT37 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs749188068, COSV99845629; called by muse, mutect2
- LCN9 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 71/257 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs193005693; called by muse, mutect2, varscan2
- MAP2 | c.1230A>C p.E410D | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.571); catalogued as rs780766647, COSV52280860; called by muse, mutect2, varscan2
- MROH5 | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 55/425 reads (13%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.458); catalogued as rs772141515; called by muse, mutect2, varscan2
- MTNR1B | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as CM121597; called by muse, mutect2, varscan2
- OBSL1 | c.4405G>A p.E1469K | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs780528802, COSV54703780; called by muse, mutect2, varscan2
- OR5T2 | c.904A>C p.S302R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs867798059, COSV57588098; called by muse, mutect2, varscan2
- PLEC | c.8506G>A p.A2836T (on ENST00000322810 / NM_201380.4; = p.A2726T on NM_000445.5) | Missense Mutation (SNP) | VAF 109/675 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs782264628, COSV59630379; called by muse, mutect2, varscan2
- PTPRT | c.3470G>A p.R1157H | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201275244, COSV61962377; called by muse, mutect2, varscan2
- SDK1 | c.4898C>T p.T1633M | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs140602039; called by muse, mutect2
- SNX9 | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.763); catalogued as rs533381984; called by muse, mutect2, varscan2
- SPINT3 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1348455327, COSV54155367; called by muse, mutect2, varscan2
- SS18L1 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.469); catalogued as rs756376662; called by muse, mutect2, varscan2
- SYNE1 | c.463G>A p.V155M (on ENST00000367255 / NM_182961.4; = p.V162M on NM_033071.3) | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs774342833, COSV54933314; called by muse, mutect2, varscan2
- TEX13C | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.088); catalogued as rs1217207081, COSV50143683; called by muse, mutect2
- TFIP11 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373604642; called by muse, mutect2, varscan2
- TLE1 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs61733323; called by muse, mutect2, varscan2
- TRIM51 | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV55266551; called by muse, mutect2, varscan2
- TRIM51 | c.1204G>T p.V402F | Missense Mutation (SNP) | VAF 103/451 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99792900; called by muse, mutect2, varscan2
- TRPM6 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs768922534, COSV62513869; called by muse, mutect2, varscan2
- XCR1 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 89/154 reads (58%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs746145944, COSV58570861; called by muse, mutect2, varscan2
- ZNF213 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV67727900; called by muse, mutect2, varscan2
- ABCA13 | c.3958T>G p.F1320V | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2
- ABCA2 | c.5338G>T p.A1780S (on ENST00000614293; = p.A1750S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCF2 | c.1510G>C p.G504R | Missense Mutation (SNP) | VAF 83/141 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABI1 | c.821A>G p.E274G | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- ACAA2 | c.1110-2A>G p.X370_splice | Splice Site (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- AL353753.1 | n.373A>C | Splice Region (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- BPIFB4 | c.1821+1del | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by mutect2, pindel, varscan2
- DCHS1 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 145/470 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DIP2B | c.2718A>C p.K906N | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- GOLGA6L6 | c.336G>C p.E112D | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- HENMT1 | c.361C>G p.R121G | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KIAA1522 | c.3002A>T p.D1001V (on ENST00000373480 / NM_001198972.2; = p.D1060V on NM_020888.3) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- KIF24 | c.1840C>T p.H614Y | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- KRBA2 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KY | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 123/228 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NCR3LG1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR8B4 | c.709T>G p.F237V | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); called by muse, mutect2
- PAK4 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PBXIP1 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PCDHA10 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 276/896 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PLCB4 | c.3409A>G p.K1137E | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- PLP1 | c.191+8C>A | Splice Region (SNP) | VAF 19/398 reads (5%) | called by muse, mutect2
- PLXNA4 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 93/181 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLD1 | c.998C>G p.P333R | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PPEF2 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RAPGEF5 | c.754C>T p.H252Y (on ENST00000401957 / NM_001367602.2; = p.H555Y on NM_012294.5) | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- RB1CC1 | c.4266T>A p.D1422E | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF165 | c.615+2T>C p.X205_splice | Splice Site (SNP) | VAF 46/113 reads (41%) | called by muse, mutect2, varscan2
- SCN4A | c.2236G>A p.D746N | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SEC14L6 | c.566T>A p.L189* | Nonsense Mutation (SNP) | VAF 40/165 reads (24%) | called by muse, mutect2, varscan2
- SHLD2 | c.2456_2472del p.L819Rfs*27 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | called by mutect2, pindel, varscan2
- SOWAHB | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SOX9 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | called by muse, varscan2
- SPTBN2 | c.6358G>A p.D2120N | Missense Mutation (SNP) | VAF 19/520 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2
- SYNE1 | c.4722del p.K1574Nfs*32 (on ENST00000367255 / NM_182961.4; = p.K1581Nfs*32 on NM_033071.3) | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | called by mutect2, pindel, varscan2
- TFEC | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- TIPARP | c.1247+2T>A p.X416_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- TMPRSS11D | c.494C>A p.A165E | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TRIM23 | c.274_275insC p.N92Tfs*37 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- TRPS1 | c.2213A>T p.E738V (on ENST00000220888 / NM_001330599.2; = p.E751V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/729 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- VARS2 | c.2164C>T p.L722F | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZDBF2 | c.3690C>A p.D1230E | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- ZNF117 | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2
- ABCG8 | c.1911G>A p.S637= | Silent (SNP) | VAF 211/703 reads (30%) | catalogued as rs200406894; called by muse, mutect2, varscan2
- BBS9 | c.1911G>T p.S637= (on ENST00000242067 / NM_001348036.1; = p.S597= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/223 reads (17%) | catalogued as COSV99630481; called by muse, mutect2, varscan2
- CCDC141 | c.3750G>A p.G1250= | Silent (SNP) | VAF 59/414 reads (14%) | called by muse, mutect2, varscan2
- CDS2 | c.747C>T p.T249= | Silent (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- CELSR1 | c.5766C>T p.C1922= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs771398493, COSV53087004; called by muse, mutect2, varscan2
- CFAP161 | c.432G>A p.G144= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- CNTN5 | c.720G>A p.A240= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as rs749442209, COSV54288611, COSV99682538; called by muse, mutect2, varscan2
- COL1A2 | c.3402A>G p.E1134= | Silent (SNP) | VAF 9/244 reads (4%) | catalogued as COSV51955221, COSV99800554; called by muse, mutect2
- CPXCR1 | c.228C>A p.I76= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV52161924, COSV52164465; called by muse, mutect2, varscan2
- EML1 | c.1248A>G p.E416= | Silent (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- GCGR | c.1101C>T p.F367= | Silent (SNP) | VAF 68/494 reads (14%) | catalogued as rs374992343; called by muse, mutect2, varscan2
- GH2 | c.558C>T p.Y186= | Silent (SNP) | VAF 35/730 reads (5%) | catalogued as rs144217364; called by muse, mutect2
- GJA8 | c.366C>T p.G122= | Silent (SNP) | VAF 79/357 reads (22%) | catalogued as rs782125496; called by muse, mutect2, varscan2
- GLDC | c.492C>T p.Y164= | Silent (SNP) | VAF 67/256 reads (26%) | called by muse, mutect2, varscan2
- GRM1 | c.717C>T p.S239= | Silent (SNP) | VAF 44/295 reads (15%) | catalogued as rs956460815, COSV51266471; called by muse, mutect2, varscan2
- KIZ | c.891C>T p.S297= | Silent (SNP) | VAF 38/286 reads (13%) | catalogued as rs768777591, COSV55687874; called by muse, mutect2, varscan2
- KMT2A | c.2844G>A p.V948= | Silent (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- NHLRC1 | c.414G>A p.T138= | Silent (SNP) | VAF 88/290 reads (30%) | catalogued as COSV61481555; called by muse, mutect2, varscan2
- NWD1 | c.3828G>A p.S1276= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as rs769843259, COSV60342128; called by muse, mutect2, varscan2
- PCDHA12 | c.1257G>A p.S419= | Silent (SNP) | VAF 20/666 reads (3%) | catalogued as rs781841207, COSV56532300; called by muse, mutect2
- PCDHGA6 | c.1734G>A p.A578= | Silent (SNP) | VAF 162/563 reads (29%) | catalogued as rs376557886, COSV53953262, COSV53999620; called by muse, mutect2, varscan2
- RBMXL3 | c.195C>T p.A65= | Silent (SNP) | VAF 57/181 reads (31%) | catalogued as rs782641878; called by muse, mutect2, varscan2
- SHE | c.678C>T p.D226= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as rs745452697, COSV59071083; called by muse, mutect2, varscan2
- SOGA3 | c.633G>A p.G211= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs1321941111; called by muse, mutect2, varscan2
- ST6GAL2 | c.93C>T p.T31= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs772783258, COSV64527457; called by muse, mutect2, varscan2
- TRDN | c.558C>T p.H186= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- UNC45B | c.1416C>A p.T472= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- AC138647.1 | chr8:141514695 G>A | 5'Flank (SNP) | VAF 34/156 reads (22%) | called by muse, mutect2, varscan2
- AGAP14P | n.1462A>T | RNA (SNP) | VAF 22/706 reads (3%) | called by muse, mutect2
- ARHGAP27P2 | n.242C>A | RNA (SNP) | VAF 40/144 reads (28%) | called by muse, varscan2
- ARMC5 | c.1864+155C>T | Intron (SNP) | VAF 118/417 reads (28%) | catalogued as rs751121602, COSV51654855; called by muse, mutect2, varscan2
- BCKDHA | c.485-383C>T | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- CHCHD3 | c.170-10224T>A | Intron (SNP) | VAF 18/568 reads (3%) | called by muse, mutect2
- DAZL | c.3+705C>T | Intron (SNP) | VAF 19/70 reads (27%) | catalogued as rs1339435741; called by muse, mutect2, varscan2
- DOCK2 | c.2800-48359G>T | Intron (SNP) | VAF 37/126 reads (29%) | called by mutect2, varscan2
- EPB41 | c.-641C>G | 5'UTR (SNP) | VAF 19/103 reads (18%) | catalogued as rs538283470; called by muse, mutect2, varscan2
- GNRH1 | c.-34G>A | 5'UTR (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- IL3RA | c.-7G>A | 5'UTR (SNP) | VAF 7/52 reads (13%) | catalogued as rs748843004, COSV100452205; called by muse, mutect2, varscan2
- KLK12 | c.37+90T>G | Intron (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- OR51F5P | n.879C>A | RNA (SNP) | VAF 43/189 reads (23%) | called by muse, mutect2, varscan2
- OR7A2P | n.678T>C | RNA (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2
- PIK3C2B | c.934-1653C>T | Intron (SNP) | VAF 56/140 reads (40%) | called by muse, mutect2, varscan2
- RALGPS1 | c.*13C>T | 3'UTR (SNP) | VAF 34/158 reads (22%) | catalogued as rs753106642; called by muse, mutect2, varscan2
- RIMS1 | c.3398+15C>A | Intron (SNP) | VAF 13/290 reads (4%) | called by muse, mutect2
- TPK1 | c.258+2648T>G | Intron (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- TRPS1 | c.2661+71724G>C | Intron (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
